Somatic mutation profile of tumor specimen 1105253 (aliquot 7316UP-1135-1105253) from CPTAC case C287328, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105253: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdaa402c-021e-457b-9c63-56aac5b3e817.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105211 (Blood Derived Normal), aliquot 7316UP-534-1105211; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a886b07-f5a3-4f72-9da5-768ba144063f

The open-access MAF lists 77 somatic variants for this specimen: 51 protein-altering or splice-affecting, 18 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 18, Intron 5, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 3, In Frame Ins 1, 5'Flank 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKS1B | c.3265C>T p.R1089W (on ENST00000547776 / NM_152788.4; = p.R255W on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1410929626, COSV59115659; called by muse, mutect2, varscan2
- BCL6B | c.125del p.L42Rfs*71 | Frame Shift Del (DEL) | VAF 45/209 reads (22%) | catalogued as rs1270114003; called by mutect2, pindel, varscan2
- ELP3 | c.412A>C p.I138L | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as rs554926933; called by muse, mutect2, varscan2
- F2RL3 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 69/315 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50185415, COSV50187057; called by muse, mutect2, varscan2
- FRG2C | c.821C>A p.S274* | Nonsense Mutation (SNP) | VAF 69/661 reads (10%) | catalogued as rs1392451749; called by muse, mutect2
- FSCN1 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as rs1228866091; called by muse, mutect2
- HPGDS | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148462970; called by muse, mutect2, varscan2
- LRCH1 | c.1037G>A p.S346N | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs941415221; called by muse, mutect2, varscan2
- MAPK15 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs782239626, COSV100567821; called by muse, mutect2, varscan2
- MBD3L2 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 64/601 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs772576142; called by muse, mutect2, varscan2
- OR4K15 | c.908C>T p.T303M (on ENST00000305051; = p.T279M on NM_001005486.1) | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs150969455, COSV59301119; called by muse, mutect2, varscan2
- OR8K3 | c.475G>T p.V159F | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.078); catalogued as COSV57130928; called by muse, mutect2, varscan2
- POTEE | c.2572G>A p.G858R | Missense Mutation (SNP) | VAF 143/622 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (1); catalogued as rs766185047; called by muse, mutect2, varscan2
- SLC3A1 | c.675G>T p.L225F | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); catalogued as COSV53222851; called by muse, mutect2
- TAS2R14 | c.18G>C p.K6N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.066); catalogued as rs752990727; called by muse, mutect2
- TTN | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 73/271 reads (27%) | PolyPhen benign (0.02); catalogued as rs754127089, COSV59954418; called by muse, mutect2, varscan2
- AASDH | c.3286A>T p.N1096Y | Missense Mutation (SNP) | VAF 24/355 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- ADGRL1 | c.1132G>T p.D378Y (on ENST00000340736 / NM_001008701.3; = p.D373Y on NM_014921.5) | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AJAP1 | c.973_975dup p.Q325dup | In Frame Ins (INS) | VAF 45/271 reads (17%) | called by mutect2, pindel, varscan2
- ANKFN1 | c.1599_1603del p.Y534* | Frame Shift Del (DEL) | VAF 35/177 reads (20%) | called by mutect2, pindel, varscan2
- ATP11B | c.2706_2707del p.Q904Afs*5 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- CCDC168 | c.17026G>C p.E5676Q | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- CHRM3 | c.449T>A p.V150E | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTAGE4 | c.2277G>C p.R759S | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.637); called by mutect2, varscan2
- DNAH7 | c.5146A>G p.M1716V | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2
- DTNA | c.604-2A>T p.X202_splice | Splice Site (SNP) | VAF 36/233 reads (15%) | called by muse, mutect2, varscan2
- ELMOD2 | c.138G>T p.R46S | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM102A | c.922A>T p.K308* (on ENST00000373095 / NM_001035254.3; = p.K166* on NM_203305.2) | Nonsense Mutation (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- FHDC1 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FHDC1 | c.2776G>C p.G926R | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FSHR | c.152+2T>C p.X51_splice | Splice Site (SNP) | VAF 116/457 reads (25%) | called by muse, mutect2, varscan2
- GID4 | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2
- LGALS12 | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 30/577 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2
- MAML3 | c.795C>A p.S265R | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- MDC1 | c.3339del p.R1114Efs*2 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel, varscan2
- MEPE | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- MS4A18 | c.224G>T p.S75I | Missense Mutation (SNP) | VAF 25/339 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2
- MYO3B | c.2066G>A p.G689E | Missense Mutation (SNP) | VAF 107/405 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NACC1 | c.1221_1226+11del p.X407_splice | Splice Site (DEL) | VAF 31/153 reads (20%) | called by mutect2, pindel
- NT5E | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PCDH11X | c.3056C>A p.S1019Y | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2
- PRPH2 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 34/556 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2
- PSG7 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 101/305 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PTGS2 | c.1594A>T p.K532* | Nonsense Mutation (SNP) | VAF 41/163 reads (25%) | called by muse, mutect2, varscan2
- RET | c.2156T>A p.F719Y | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RTN4IP1 | c.150A>T p.K50N | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SCRT1 | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.098); called by mutect2, varscan2
- SPAM1 | c.971C>T p.T324I | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- WDR5B | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- YIPF7 | c.467T>C p.F156S | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF629 | c.1150A>T p.T384S | Missense Mutation (SNP) | VAF 66/355 reads (19%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AKAP9 | c.573G>A p.Q191= | Silent (SNP) | VAF 43/340 reads (13%) | catalogued as rs1193980374, COSV100663516; called by muse, mutect2, varscan2
- CCN4 | c.489G>A p.P163= | Silent (SNP) | VAF 108/369 reads (29%) | catalogued as rs368562535; called by muse, mutect2, varscan2
- CHRNG | c.369G>A p.E123= | Silent (SNP) | VAF 24/466 reads (5%) | called by muse, mutect2
- CYTH3 | c.549C>G p.V183= | Silent (SNP) | VAF 70/378 reads (19%) | called by muse, mutect2, varscan2
- FAM186B | c.1176T>C p.L392= | Silent (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- FSCN1 | c.1440C>T p.A480= | Silent (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- GRAMD1B | c.555G>A p.S185= | Silent (SNP) | VAF 45/161 reads (28%) | catalogued as rs373203630; called by muse, mutect2, varscan2
- IGLC7 | c.141C>T p.S47= | Silent (SNP) | VAF 223/734 reads (30%) | called by muse, varscan2
- LY9 | c.996C>T p.A332= | Silent (SNP) | VAF 52/218 reads (24%) | catalogued as rs763617259, COSV54439199; called by muse, mutect2, varscan2
- MAGEA6 | c.522C>T p.H174= | Silent (SNP) | VAF 125/176 reads (71%) | catalogued as rs1556826517, COSV61448746, COSV61448773; called by muse, mutect2, varscan2
- NSD1 | c.6501C>T p.C2167= | Silent (SNP) | VAF 63/226 reads (28%) | catalogued as rs545207228; called by muse, mutect2, varscan2
- PARP12 | c.2098C>A p.R700= | Silent (SNP) | VAF 59/532 reads (11%) | catalogued as rs140064898; called by muse, mutect2
- PAX4 | c.489G>T p.R163= | Silent (SNP) | VAF 65/403 reads (16%) | catalogued as COSV58388457; called by muse, mutect2, varscan2
- PITPNM1 | c.306T>A p.P102= | Silent (SNP) | VAF 26/135 reads (19%) | called by muse, mutect2, varscan2
- PROCR | c.387C>G p.V129= | Silent (SNP) | VAF 34/436 reads (8%) | called by muse, mutect2
- RFNG | c.846G>T p.G282= | Silent (SNP) | VAF 41/142 reads (29%) | called by muse, mutect2, varscan2
- TLR10 | c.2106G>A p.Q702= | Silent (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2, varscan2
- VIRMA | c.3666C>A p.T1222= | Silent (SNP) | VAF 70/146 reads (48%) | called by muse, mutect2, varscan2
- ABCA13 | c.14744+8947G>T | Intron (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- ABCC13 | n.4036C>G | RNA (SNP) | VAF 50/183 reads (27%) | catalogued as rs913239027; called by muse, mutect2, varscan2
- KCNAB2 | c.1014+82G>A | Intron (SNP) | VAF 43/150 reads (29%) | catalogued as rs1165321331, COSV99312229; called by muse, mutect2, varscan2
- MCF2L2 | c.1862+3831_1862+3834del | Intron (DEL) | VAF 16/50 reads (32%) | catalogued as rs778247162; called by pindel, varscan2
- MICU1 | c.537+9880G>C | Intron (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- NXPH3 | c.*2404C>A | 3'UTR (SNP) | VAF 15/276 reads (5%) | called by muse, mutect2
- OPRM1 | chr6:154039227 del C | 5'Flank (DEL) | VAF 18/122 reads (15%) | called by mutect2, pindel, varscan2
- SFI1 | c.3069-69C>T | Intron (SNP) | VAF 22/132 reads (17%) | called by muse, mutect2, varscan2
